Surgical pathology report (de-identified scan), TCGA case TCGA-DD-A4NR, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-A4NR-01A (Primary Tumor).

ICD-O-3

Carcinoma, hepatocellular NOS
8170/3

Site: Liver C22.0
9/12/12

REVISED REPORT (Addendum/Procedure included)

TISSUE DESCRIPTION:

A1 A2 A3 A4 A5

Portion of liver segment VIII (110 grams, 8.5 x 8.5 x 6.0 cm).

DIAGNOSIS:

Liver, segment VIII, excision: Grade 3 (of 4) hepatocellular carcinoma, usual type, forming a 5.0 x 4.5 x 4.0 cm mass. The tumor is located in segment VIII. The hepatic capsule is free of tumor. The surgical margins are free of tumor, the clearance being 1.6 cm grossly. Extratumoral vascular invasion is not identified. The tumor is not encapsulated, infiltration of parenchyma being of pushing type. Non-neoplastic liver will be reported in an addendum.

ADDENDUM:

The non-neoplastic liver is consistent with primary biliary cirrhosis stage 4 (of 4). Iron is negative for hemosiderosis. Trichrome stain highlights bridging fibrosis with regenerative nodules.

Source: NCI Genomic Data Commons file e3cbf495-9af4-4b7e-aba0-7ce378812708 (TCGA-DD-A4NR.93133C58-B1BF-4A5C-8EFC-AE17EC6A0B64.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).